MMRF case MMRF_2001 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b6defce8-cf09-497d-b3c8-2a7ac831bcae

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.6 years (21,056 days); ISS stage: II; Days to last known disease status: 907 days (2.5 years); Days to last follow up: 907 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 103 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 404 days (1.1 years); Days to treatment end: 549 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -82 (ECOG 1): M Protein 6.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 73.6 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.74 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 12.2 g/dL; Glucose 9.08 mmol/L; C-Reactive Protein 0.268 mg/dL.
- Day 40 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 7.32 mmol/L; Total Protein 6.6 g/dL.
- Day 110 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.88 µg/mL; Creatinine 88.4 µmol/L; Calcium 2.13 mmol/L; Total Protein 6.2 g/dL.
- Day 214: M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.83 g/L; Beta 2 Microglobulin 1.97 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 10.8 mmol/L.
- Day 253: Hemoglobin 8.12 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6.6 mmol/L.
- Day 319: M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 8.58 mmol/L.
- Day 431: M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.2 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 11.5 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.56 mmol/L.
- Day 543 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.83 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 11.4 mmol/L.
- Day 586: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 10.2 mmol/L.
- Day 725: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 8 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 12.7 mmol/L.
- Day 795 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.67 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 6.93 mmol/L.
- Day 907: M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 12.6 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 10 mmol/L.

Other clinical attributes
- Day -82: Weight: 107 kg; Height: 183 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2001_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -82 days.
- Sample MMRF_2001_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -82 days.
